Somatic mutation profile of tumor specimen MP2PRT-PARNSB-TMP1-A (aliquot MP2PRT-PARNSB-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNSB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Chronic lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,170 days).
Specimen MP2PRT-PARNSB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193a21a5-c1c5-48d7-80de-a4defbef0897.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNSB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNSB-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76db8b77-6569-410b-8222-ed6368530809

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, 5'Flank 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD9 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 210/674 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761934433, COSV60245090; called by muse, mutect2, varscan2
- CCAR1 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99771079; called by muse, mutect2, varscan2
- CDH22 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as rs376156631; called by muse, mutect2, varscan2
- KRT84 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 225/728 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs570049642; called by muse, mutect2, varscan2
- PPP2R1B | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as COSV100232390; called by muse, mutect2
- TET3 | c.4750C>G p.L1584V | Missense Mutation (SNP) | VAF 166/575 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV69641146; called by muse, mutect2, varscan2
- ZMYND15 | c.2222G>A p.R741Q (on ENST00000433935 / NM_001136046.3; = p.R702Q on NM_032265.2) | Missense Mutation (SNP) | VAF 125/412 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs1473174979; called by muse, mutect2, varscan2
- ABCA3 | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 115/385 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C2orf16 | c.1239C>G p.I413M | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CNNM1 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 28/733 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- ELK3 | c.889_904del p.L297Pfs*40 | Frame Shift Del (DEL) | VAF 66/587 reads (11%) | called by mutect2, pindel
- PALMD | c.626T>A p.V209D | Missense Mutation (SNP) | VAF 91/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTLC3 | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UHRF1 | c.272C>G p.S91C (on ENST00000612630 / NM_001290050.1; = p.S104C on NM_013282.4) | Missense Mutation (SNP) | VAF 22/716 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- USH2A | c.9256C>G p.Q3086E | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAM33 | c.948C>G p.V316= | Silent (SNP) | VAF 204/666 reads (31%) | catalogued as rs903129772; called by muse, mutect2, varscan2
- AP1S3 | c.231G>A p.E77= | Silent (SNP) | VAF 94/327 reads (29%) | catalogued as rs1284520519; called by muse, mutect2, varscan2
- DDAH1 | c.90G>A p.L30= | Silent (SNP) | VAF 213/779 reads (27%) | called by muse, mutect2, varscan2
- DOP1B | c.3846C>T p.L1282= | Silent (SNP) | VAF 161/522 reads (31%) | catalogued as rs754084399; called by muse, mutect2, varscan2
- ELK3 | c.423C>T p.G141= | Silent (SNP) | VAF 88/601 reads (15%) | called by muse, mutect2, varscan2
- MIB1 | c.1257G>A p.L419= | Silent (SNP) | VAF 32/327 reads (10%) | catalogued as COSV55095762; called by muse, mutect2
- OR13C5 | c.144C>T p.I48= | Silent (SNP) | VAF 87/465 reads (19%) | called by muse, mutect2
- TMEM104 | c.33C>G p.L11= | Silent (SNP) | VAF 104/349 reads (30%) | called by muse, mutect2, varscan2
- USP17L7 | c.1176A>G p.R392= | Silent (SNP) | VAF 120/935 reads (13%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27574153 C>T | 5'Flank (SNP) | VAF 108/313 reads (35%) | catalogued as rs1045009686; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | chr22:44702306 G>A | 5'Flank (SNP) | VAF 179/640 reads (28%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1903+96C>G | Intron (SNP) | VAF 21/548 reads (4%) | called by muse, mutect2
